Somatic mutation profile of tumor specimen TCGA-B0-5691-01A (aliquot TCGA-B0-5691-01A-11D-1534-10) from TCGA case TCGA-B0-5691, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 66.0 years (24,120 days).
Specimen TCGA-B0-5691-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7d3419d-b2dc-468a-a3c0-8de4c9056168.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5691-11A (Solid Tissue Normal), aliquot TCGA-B0-5691-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5b83e5c-aab5-43c0-aec3-8a37733518d2

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Frame Shift Ins 3, Frame Shift Del 2, In Frame Del 2, Nonsense Mutation 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.3245G>T p.S1082I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV60047392; called by muse, mutect2, varscan2
- ANLN | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56077240; called by muse, mutect2
- ARMC4 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs375702916; called by muse, mutect2, varscan2
- BRCC3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV57462323; called by muse, mutect2, varscan2
- C9orf85 | c.20A>T p.N7I | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58254722; called by muse, mutect2, varscan2
- CARS2 | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57286902; called by muse, mutect2, varscan2
- CDV3 | c.409T>C p.S137P | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV53912340; called by muse, mutect2, varscan2
- CPED1 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60005160; called by muse, mutect2, varscan2
- CUL7 | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54818666, COSV54821885; called by muse, mutect2, varscan2
- DNAI4 | c.465A>C p.E155D | Missense Mutation (SNP) | VAF 131/518 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64018964; called by muse, mutect2, varscan2
- FCGRT | c.305T>A p.F102Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as COSV55530048; called by muse, mutect2, varscan2
- FCRL5 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs771525110, COSV62516014; called by muse, mutect2, varscan2
- GALNT10 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51728521; called by muse, varscan2
- ICE2 | c.2285A>T p.K762I | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV55031951; called by muse, mutect2, varscan2
- INTS13 | c.559A>G p.N187D | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV53903375; called by muse, mutect2, varscan2
- IPO7 | c.2343G>A p.M781I | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.643); catalogued as COSV65685673; called by muse, mutect2, varscan2
- LIG1 | c.1755G>T p.K585N | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.136); catalogued as COSV54393001; called by muse, mutect2, varscan2
- LPAR4 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 102/418 reads (24%) | catalogued as COSV70912842; called by muse, mutect2, varscan2
- LRRCC1 | c.1186A>C p.N396H | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.659); catalogued as COSV64483906; called by muse, mutect2, varscan2
- LRRTM2 | c.712T>G p.W238G | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51222619; called by muse, mutect2, varscan2
- MKKS | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV61399077; called by muse, mutect2
- MMP2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.385); catalogued as COSV54602564; called by muse, mutect2, varscan2
- MTOR | c.7000T>G p.L2334V | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63869177; called by muse, mutect2, varscan2
- NFATC4 | c.2048T>G p.F683C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51605135; called by muse, mutect2, varscan2
- NFIA | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV64539450; called by muse, mutect2, varscan2
- OR10G4 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201358968; called by muse, mutect2
- OR2J2 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65848113; called by muse, mutect2
- PER1 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV57920383; called by muse, mutect2, varscan2
- PRB4 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.556); catalogued as COSV54397673; called by muse, varscan2
- RBM34 | c.1093A>C p.K365Q | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV64012926; called by muse, mutect2, varscan2
- RBM8A | c.491G>T p.R164I | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57162797; called by muse, mutect2, varscan2
- RESF1 | c.309A>C p.Q103H | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV100440740, COSV57022010, COSV57023164; called by muse, mutect2
- ROCK2 | c.2390A>T p.E797V | Missense Mutation (SNP) | VAF 108/628 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59959468; called by muse, varscan2
- ROCK2 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 106/621 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV59959491; called by muse, varscan2
- S1PR4 | c.1126T>C p.S376P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1192399616, COSV55740603; called by muse, mutect2
- SUN5 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1329379104, COSV62181554; called by muse, mutect2, varscan2
- VHL | c.493del p.V165Lfs*5 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | catalogued as CM031757, CM074631, COSV56566513; called by mutect2, pindel, varscan2
- ZHX3 | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | catalogued as COSV58385106; called by muse, mutect2, varscan2
- ZSCAN18 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV53734171; called by muse, mutect2, varscan2
- H2AC21 | c.282_283insTG p.N95* | Frame Shift Ins (INS) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- LAMA3 | c.1248_1249insT p.V417Cfs*5 | Frame Shift Ins (INS) | VAF 44/220 reads (20%) | called by mutect2, pindel*, varscan2
- LMO7 | c.1484dup p.L495Ffs*4 (on ENST00000357063; = p.L225Ffs*4 on NM_015842.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 23/136 reads (17%) | called by mutect2, pindel, varscan2
- SETX | c.4795_4797del p.F1599del | In Frame Del (DEL) | VAF 41/182 reads (23%) | called by mutect2, pindel, varscan2
- SMARCE1 | c.223_225del p.R75del | In Frame Del (DEL) | VAF 36/172 reads (21%) | called by mutect2, pindel, varscan2
- TRPS1 | c.3442_3469del p.N1148Dfs*8 (on ENST00000220888 / NM_001330599.2; = p.N1161Dfs*8 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/275 reads (11%) | called by mutect2, pindel
- BOC | c.246G>T p.L82= | Silent (SNP) | VAF 40/169 reads (24%) | catalogued as COSV56353219; called by muse, mutect2, varscan2
- CDH4 | c.2571C>T p.P857= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV64659782; called by muse, mutect2, varscan2
- CLCN4 | c.1428C>T p.G476= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs775225884, COSV66467014; called by muse, mutect2
- DISP2 | c.2874C>T p.H958= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- FAM47C | c.1740C>A p.S580= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV63727637; called by muse, varscan2
- GDF15 | c.195C>A p.T65= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs769807576, COSV53251319; called by muse, mutect2
- KLHL10 | c.1719A>C p.P573= | Silent (SNP) | VAF 33/186 reads (18%) | catalogued as COSV53173747; called by muse, mutect2, varscan2
- NDUFA1 | c.63G>A p.L21= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV65097527; called by muse, mutect2, varscan2
- SERPINB1 | c.723G>A p.T241= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs777703578, COSV66313786; called by muse, mutect2, varscan2
- XRN2 | c.1380A>T p.A460= | Silent (SNP) | VAF 75/294 reads (26%) | catalogued as COSV65870183; called by muse, mutect2, varscan2
- ACOT7 | c.174-8966T>A | Intron (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- SH2B2 | chr7:102282742 A>T | 5'Flank (SNP) | VAF 11/49 reads (22%) | catalogued as COSV52935208; called by muse, mutect2, varscan2
